Surgical pathology report (de-identified scan), TCGA case TCGA-SC-A6LM, project TCGA-MESO (Mesothelioma), tissue source site Memorial Sloan Kettering, specimen TCGA-SC-A6LM-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] (Age: [REDACTED] F Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]

Clinical Diagnosis & History:
History of asbestos with left pleural thickening here for liver biopsy.

Specimens Submitted:

- 1: SP: Left pleural biopsy #1 (fs)
- 2: SP: Left pleural biopsy (fs)
- 3: SP: Left pleural biopsy

DIAGNOSIS:

- 1-3. PLEURA, LEFT; BIOPSY #1, 2, 3:
-MALIGNANT MESOTHELIOMA, EPITHELIOID TYPE.
-IMMUNOHISTOCHEMISTRY SHOWS THAT THE TUMOR CELLS ARE POSITIVE FOR WT1
(WEAK), CALRETININ (WEAK), D2-40 (WEAK), AE1/AE3, AND NEGATIVE FOR TTF-1,
NAPSIN, AND BER-EP4, SUPPORTING THE DIAGNOSIS.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the
They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1). The specimen is received fresh for frozen section consultation, labeled

** Continued on next page **

CCCF ICD-O-3
Mesothelioma, diffuse, epithelioid
malignant 9052/3
path
Mesothelioma, diffuse
epithelioid, malignant 9052/3
Site (L) Pleura NOS C38.4
gw 7/5/13

[page 2 of 3]
----- Page 2 of 3
"Left pleural biopsy" and consists of an aggregate of white-tan membranous soft tissue 3.2 x 3.0 x 0.3 cm. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

3). The specimen is received fresh labeled "Left pleural biopsy." It consists of multiple pieces of brown-tan membranous soft tissue measuring 0.5 x 3 x 0.6 cm in aggregate. The specimen is sectioned and submitted entirely.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: SP: Left pleural biopsy#1(fs)

Block	Sect.	Site	PCs
1		(not entered)	6
1		fsc	1

Part 2: SP: Left pleural biopsy (fs)

Block	Sect.	Site	PCs
1		FSC	0

Part 3: SP: Left pleural biopsy

Block	Sect.	Site	PCs
3		u	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: LEFT PLEURAL BIOPSY #1(FS):
SUSPICIOUS FOR MESOTHELIOMA

PERMANENT DIAGNOSIS: SAME

2. FROZEN SECTION DIAGNOSIS: SP: LEFT PLEURAL BIOPSY #2 (FS):
SUSPICIOUS FOR MESOTHELIOMA

PERMANENT DIAGNOSIS: SAME

** Continued on next page **

[page 3 of 3]
Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: LEFT PLEURAL BIOPSY #1(FS):
SUSPICIOUS FOR MESOTHELIOMA

PERMANENT DIAGNOSIS: SAME

2. FROZEN SECTION DIAGNOSIS: SP: LEFT PLEURAL BIOPSY #2 (FS):
SUSPICIOUS FOR MESOTHELIOMA

PERMANENT DIAGNOSIS: SAME

** End of Report **

Criteria	lw. 6/27/13	Yes	No

Source: NCI Genomic Data Commons file 725e2a86-17f8-4e51-9148-d6077c6c336d (TCGA-SC-A6LM.6CF9AD5C-60BE-418D-AA95-F12B661361D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).